Somatic mutation profile of tumor specimen C3N-00494-04 (aliquot CPT0012910006) from CPTAC case C3N-00494, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.0 years (24,122 days).
Specimen C3N-00494-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df3ccc77-69a9-4ae1-84ff-b8689cdd6d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00494-31 (Blood Derived Normal), aliquot CPT0012980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bbe93db-b2c0-4a86-bb0a-1f49e0008fb1

The open-access MAF lists 124 somatic variants for this specimen: 84 protein-altering or splice-affecting, 24 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Frame Shift Del 7, Intron 5, Nonsense Mutation 5, 3'UTR 5, RNA 3, Splice Site 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691439, COSV63973975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCDIN3D | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 47/275 reads (17%) | catalogued as COSV61702721; called by muse, mutect2, varscan2
- FAM13A | c.1390A>C p.S464R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52008762; called by muse, mutect2, varscan2
- IL20RA | c.1381G>C p.A461P | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1243457821; called by muse, mutect2, varscan2
- KCNA2 | c.317del p.L106* | Frame Shift Del (DEL) | VAF 176/396 reads (44%) | catalogued as COSV100316076; called by mutect2, pindel, varscan2
- KCTD8 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1243506439; called by muse, mutect2, varscan2
- LRRC1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63823304; called by muse, mutect2, varscan2
- NECTIN1 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99871879; called by muse, mutect2, varscan2
- OR14A2 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 94/137 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100825528; called by muse, mutect2, varscan2
- OR51I2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs750975545, COSV58299315; called by muse, mutect2, varscan2
- PITPNM3 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs941922159; called by muse, mutect2, varscan2
- PLCB1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV62046201; called by muse, mutect2, varscan2
- SIGIRR | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 88/268 reads (33%) | catalogued as rs778148546, COSV58985876; called by muse, mutect2, varscan2
- SLC19A3 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as CM131528; called by muse, mutect2, varscan2
- SLC22A14 | c.1356G>T p.L452F | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.443); catalogued as rs1343591039; called by muse, mutect2, varscan2
- SPECC1 | c.3110C>G p.P1037R | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV99821235; called by muse, mutect2, varscan2
- SYTL3 | c.1266C>G p.D422E (on ENST00000611299 / NM_001242394.1; = p.D354E on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/194 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV51914685; called by muse, mutect2, varscan2
- TMEM232 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV101459900; called by muse, mutect2, varscan2
- TSNAXIP1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs746465595; called by muse, mutect2, varscan2
- TTN | c.7720C>G p.P2574A (on ENST00000591111; = p.P2528A on NM_003319.4) | Missense Mutation (SNP) | VAF 35/183 reads (19%) | PolyPhen benign (0); catalogued as COSV59931673; called by muse, mutect2, varscan2
- VHL | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 113/171 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as CM023999, CS951541, COSV56543854, COSV56544010, COSV56545833; called by muse, mutect2, varscan2
- ZNF608 | c.3217G>T p.A1073S | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs746685214; called by muse, mutect2, varscan2
- ADAMTS2 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 188/474 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK3 | c.6349C>G p.Q2117E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ANKRD10 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ARHGAP27 | c.1166C>T p.P389L (on ENST00000428638 / NM_001282290.1; = p.P48L on NM_199282.3) | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCOR | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 172/229 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BRF2 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 194/506 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- C2orf78 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- C3 | c.4815G>T p.W1605C | Missense Mutation (SNP) | VAF 377/829 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA1 | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- COL9A1 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 187/419 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL5 | c.554-9_567del p.X185_splice | Splice Site (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel
- DBN1 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DGKG | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- DNAAF3 | c.1180A>G p.I394V (on ENST00000524407 / NM_001256715.2; = p.I441V on NM_178837.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAI2 | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELN | c.1556T>G p.I519S | Missense Mutation (SNP) | VAF 459/983 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EXOC2 | c.2725T>A p.L909M | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- EXOC2 | c.2724C>A p.H908Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.14408C>T p.S4803F | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- GPR75 | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GREB1L | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRK7 | c.375_376del p.L126Qfs*14 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel, varscan2
- ITGAX | c.1390T>A p.S464T | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KATNB1 | c.1706G>C p.S569T | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KATNB1 | c.1708A>G p.K570E | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- KMT2C | c.247del p.T83Qfs*22 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | called by mutect2, pindel, varscan2
- KRTAP11-1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 142/376 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- L3MBTL1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LYPLA2 | c.428del p.V143Gfs*3 | Frame Shift Del (DEL) | VAF 70/174 reads (40%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MEX3B | c.1051C>G p.P351A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MINDY1 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MKS1 | c.16T>A p.W6R | Missense Mutation (SNP) | VAF 163/459 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MUC19 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- MYLK | c.4494T>G p.Y1498* | Nonsense Mutation (SNP) | VAF 212/472 reads (45%) | called by muse, mutect2, varscan2
- NRK | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUGGC | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 137/368 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBRM1 | c.1682del p.I561Tfs*8 | Frame Shift Del (DEL) | VAF 65/121 reads (54%) | called by mutect2, pindel, varscan2
- PCDHA6 | c.2239A>T p.S747C | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- PTK7 | c.1641G>A p.W547* | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- PTPN13 | c.6840del p.I2280Mfs*17 (on ENST00000411767 / NM_080683.3; = p.I2261Mfs*17 on NM_006264.3) | Frame Shift Del (DEL) | VAF 64/155 reads (41%) | called by mutect2, pindel, varscan2
- RAB36 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASD1 | c.479_482dup p.E161Dfs*224 | Frame Shift Ins (INS) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- RMND5B | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SALL3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SLC15A2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35F5 | c.731G>C p.S244T | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SNAP29 | c.565T>A p.Y189N | Missense Mutation (SNP) | VAF 195/509 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SORCS3 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SPRED1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- STPG1 | c.532del p.R178Efs*23 (on ENST00000337248 / NM_001199013.2; = p.R131Efs*23 on NM_178122.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- SUDS3 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TACR1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 158/233 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TBX22 | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- TCEAL4 | c.306T>A p.S102R | Missense Mutation (SNP) | VAF 141/173 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM26 | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTC21B | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TTN | c.14998C>T p.Q5000* (on ENST00000591111; = p.Q4073* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/152 reads (39%) | called by muse, mutect2, varscan2
- USP34 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZBED1 | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF707 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- A1CF | c.984C>G p.T328= | Silent (SNP) | VAF 179/357 reads (50%) | called by muse, mutect2, varscan2
- CIR1 | c.570G>A p.L190= | Silent (SNP) | VAF 19/218 reads (9%) | catalogued as rs1376105599; called by muse, mutect2
- CXCR2 | c.742C>A p.R248= | Silent (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- GFM1 | c.897C>T p.S299= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs763546447, COSV51833240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLUL | c.963C>T p.A321= | Silent (SNP) | VAF 354/540 reads (66%) | catalogued as rs770429686; called by muse, mutect2, varscan2
- GRID2IP | c.120C>G p.A40= | Silent (SNP) | VAF 72/546 reads (13%) | catalogued as rs937048848; called by muse, mutect2, varscan2
- HHLA1 | c.720C>G p.T240= | Silent (SNP) | VAF 85/228 reads (37%) | called by muse, mutect2, varscan2
- KANSL3 | c.2484G>A p.Q828= (on ENST00000666923 / NM_001349262.2; = p.Q802= on NM_001115016.3) | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs1167004067; called by muse, mutect2, varscan2
- KIF20B | c.4479T>A p.R1493= (on ENST00000371728 / NM_001284259.2; = p.R1453= on NM_016195.4) | Silent (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2
- L3HYPDH | c.315C>T p.G105= | Silent (SNP) | VAF 94/249 reads (38%) | catalogued as rs1426392566; called by muse, mutect2
- LRRC70 | c.606T>C p.H202= | Silent (SNP) | VAF 76/189 reads (40%) | called by muse, mutect2, varscan2
- MAP6 | c.1185G>A p.R395= | Silent (SNP) | VAF 71/366 reads (19%) | called by muse, mutect2, varscan2
- MC2R | c.567C>T p.I189= | Silent (SNP) | VAF 100/192 reads (52%) | catalogued as rs267605119, COSV59617516; called by muse, mutect2, varscan2
- OR10H2 | c.849G>A p.T283= | Silent (SNP) | VAF 39/323 reads (12%) | catalogued as rs563913841; called by muse, mutect2, varscan2
- OSBPL3 | c.120A>G p.G40= | Silent (SNP) | VAF 66/217 reads (30%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.2349C>A p.G783= | Silent (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- RGMA | c.375C>T p.R125= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV61235389; called by muse, mutect2, varscan2
- RPTOR | c.2226G>A p.L742= | Silent (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- SMPD3 | c.1005A>T p.A335= | Silent (SNP) | VAF 124/242 reads (51%) | called by muse, mutect2, varscan2
- SNX2 | c.27G>A p.P9= | Silent (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- SORCS3 | c.876G>T p.R292= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV100865649, COSV63826086; called by muse, mutect2, varscan2
- SPTA1 | c.3102G>A p.L1034= | Silent (SNP) | VAF 68/504 reads (13%) | called by muse, mutect2, varscan2
- WDR87 | c.6990C>T p.S2330= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1425307857; called by muse, mutect2
- ZACN | c.825C>A p.L275= | Silent (SNP) | VAF 106/299 reads (35%) | called by muse, mutect2, varscan2
- AC011525.1 | n.866del | RNA (DEL) | VAF 57/209 reads (27%) | called by mutect2, pindel, varscan2
- AC093582.1 | n.174G>A | RNA (SNP) | VAF 47/390 reads (12%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 8/66 reads (12%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- ALX4 | c.*26C>G | 3'UTR (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- ATP1A3 | c.*52C>T | 3'UTR (SNP) | VAF 30/314 reads (10%) | catalogued as rs370433301; called by muse, mutect2
- CROCC | c.1808+870C>A | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- GOLGA6L17P | n.110del | RNA (DEL) | VAF 38/442 reads (9%) | called by mutect2, pindel
- LAG3 | c.-6G>A | 5'UTR (SNP) | VAF 24/162 reads (15%) | catalogued as rs370952537; called by muse, varscan2
- MTHFD1 | c.2279+37A>C | Intron (SNP) | VAF 84/209 reads (40%) | called by muse, mutect2, varscan2
- RBBP4 | c.1212+616A>T | Intron (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- SMTN | c.2603+1062G>A | Intron (SNP) | VAF 68/184 reads (37%) | catalogued as rs765152030; called by muse, mutect2, varscan2
- SOD1 | c.-33C>G | 5'UTR (SNP) | VAF 43/215 reads (20%) | catalogued as rs749428274, COSV54256572, COSV99531978; called by muse, mutect2, varscan2
- SYT5 | c.*40C>G | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- TNFRSF10B | c.*1522T>G | 3'UTR (SNP) | VAF 141/681 reads (21%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071635 T>G | 3'Flank (SNP) | VAF 108/358 reads (30%) | called by muse, varscan2
- ZNF99 | c.*3334A>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
